Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0VZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0VZ-01A (Primary Tumor).

ICD-0-3

adenocarcinoma, endometrium, NOS 8380/3

Site: endometrium, NOS C54.1

hw
5/1/11

PATIENT HISTORY:

None given. LMP: Postmenopausal.

PRE-OP DIAGNOSIS: Endometrial cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Total abdominal hysterectomy with pelvic lymph node dissection.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

ARCHITECTURAL GRADE:

Well differentiated (FIGO 1)

NUCLEAR GRADE:

Well differentiated

TUMOR SIZE:

Grade 2

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT: Maximum dimension: 4.5 cm

DEPTH OF INVASION:**

Anterior endomyometrium: 10 %, Posterior endomyometrium: 30 %

ANGIOLYMPHATIC INVASION:

Greater than 1/2 thickness of myometrium

OTHER:

No

LYMPH NODES POSITIVE:

(epithelial, smooth muscle, others), Leiomyoma

LYMPH NODES EXAMINED:

Number of lymph nodes positive: 0

T STAGE, PATHOLOGIC:

Total number of lymph nodes examined: 13

N STAGE, PATHOLOGIC:

pT3a

M STAGE, PATHOLOGIC:

pN0

FIGO STAGE:

pMX

Comment:

IIIA

Note that pelvic wash specimen

was positive for malignant cells.

Source: NCI Genomic Data Commons file d57ebfdc-2422-4016-bff7-e266e2f525d5 (TCGA-BG-A0VZ.6CCCA758-AB3D-4260-BD25-16716E34B3BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).